CCDI case PBBPFA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/83b3aa33-c981-47c6-a1a0-53b3662b96b9

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 7.3 years (2,650 days).

Biospecimens (3 samples)
- Sample 0DDROE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDROH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDROI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
